Surgical pathology report (de-identified scan), TCGA case TCGA-FD-A5BT, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - University Of Chicago, specimen TCGA-FD-A5BT-01A (Primary Tumor).

[page 1 of 4]
ICD-3

Carcinoma, Urothelial NOS
8120/3

PATH Site: Bladder, lateral and
Anterior Wall C67.8

Gender: Male

CPCF Site: Bladder, lateral wall
C67.2

Race: White

Pathology Report:

A. Right pelvic lymph nodes; dissection:

- Fifteen lymph nodes, no tumor (0/15).

B. Left pelvic lymph nodes; dissection:

- Twenty-five lymph nodes, no tumor (0/25).

C. Left ureter tip; excision:

- Portion of ureter, no tumor.

D. Urinary bladder and prostate; cystoprostatectomy:

- Invasive high grade urothelial carcinoma with focal spindle cell sarcomatoid differentiation (5%), invading thru the bladder wall and into the perivesical fat, see pathologic parameters.

- Distal urethra margin, free of tumor.

- Prostate with high grade prostatic intraepithelial neoplasia and focal dense chronic active inflammation.

E. Distal left ureter; excision:

- Portion of ureter, no tumor.

F. Distal right ureter; excision:

- Portion of ureter, no tumor.

Urothelial Carcinoma Pathologic Parameters

1. Tumor type: Invasive urothelial carcinoma with focal sarcomatoid differentiation (5%).

2. Grade of tumor: High grade.

3. Depth of invasion: Extravesicular soft tissue (macroscopic).

4. Tumor distribution: Solitary, 5 cm, right lateral and anterior walls.

5. Ureteral margins: Negative for tumor.

6. Distal urethral margin: Negative for tumor.

[page 2 of 4]
7. Soft tissue margin or serosa: Negative for tumor.
8. Lymph nodes: Negative for tumor (0/40).
9. pTNM: pT3b,N0,MX.

Effective _____ his Checklist utilizes the 7th edition TNM staging system for Bladder of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

xx

[] MD

Interpretation performed by the Attending Pathologist and reviewed with the Resident/Fellow, [] MD

Electronically Signed Out by [], MD

Clinical History:

Patient is an _____ year-old male with bladder cancer undergoing cystoprostatectomy, bilateral lymph node dissection and bilateral ureter biopsies.

Specimens Received:

- A: Right pelvic lymph node
- B: Left pelvic lymph node
- C: Left ureter tip
- D: Bladder and prostate
- E: Distal left ureter
- F: Distal right ureter

Gross Description:

The specimens are received in six containers each labeled with the patient's name and medical record number.

A. The first container is additionally identified as, "#1 right pelvic lymph nodes". Received fresh and placed in formalin is an aggregate of yellow to tan lobulated fibroadipose tissue that measures 7 x 5.5 x 1 cm. The specimen is dissected for lymph nodes and is entirely submitted as follows:

- A1-2: One lymph node bisected
- A3: Three lymph nodes
- A4-6: Three lymph nodes each
- A7: One lymph node bisected
- A8-12: Remainder of specimen

B. The second container is additionally identified as, "#2 left pelvic lymph node". Received fresh and placed in formalin is an aggregate of yellow-tan lobulated fibroadipose tissue that measures 7 x 6 x 1.5 cm. The specimen is

[page 3 of 4]
dissected for lymph nodes and is entirely submitted as follows:

- B1: One lymph node bisected
- B2: Three lymph nodes
- B3: One lymph node bisected
- B4: Two lymph nodes
- B5: Three lymph nodes
- B6: Two lymph nodes
- B7: One lymph node bisected
- B8: One lymph node
- B9: One lymph node
- B10-16: Remainder of specimen

C. The third container is additionally identified as, "#3 left ureter tip".

Received fresh and placed in formalin is an unoriented portion of ureter that measures 0.6 x 0.5 cm. The external surface is white, dense, gray, smooth and glistening and focally covered by yellow lobulated adipose tissue. The specimen is bisected and entirely submitted in cassette C1.

D. Received fresh and placed in formalin is a 316.7 g, 17 x 8.5 x 4.2 cm cystoprostatectomy specimen consisting of a 7.5 x 6 x 3.5 cm bladder with attached mesenteric fat and a 5.5 x 4.2 x 3.8 cm prostate with a 34 cm long by 0.6 cm diameter rubbery catheter in place in the urethra. Also received are 2 detached vessels both 6.5 cm in length and 0.4 cm in diameter. The bladder has a 4.5 x 3.5 cm area of disruption on the lower anterior wall and the prostate has a 2.5 x 2 cm area of disruption at the apex. The right seminal vesicles measure 3 x 1.4 x 0.6 cm and right vas deferens measures 8.5 cm in length by 0.6 cm in diameter. The left seminal vesicles measures 3.5 x 1.5 x 0.7 cm and left vas deferens measures 8 cm in length by 0.5 cm in diameter. The right ureteral stump measures 2.3 cm, the left measures 2 cm, the urethral stump measures 0.7 cm, and each demonstrates an intact, patent lumen.

The right half of the prostate is inked blue and the left half is inked black. The outside of the bladder is inked black. The bladder and prostate are opened anteriorly along the urethra. The outer surface of the prostate is tan and shaggy. Sectioning demonstrates rubbery, pink-tan, peri-urethral nodularity with no discrete masses or indurations.

The opened bladder reveals a 5 x 4.5 x 2.5 cm firm, ulcerated, tan-brown mass with a heaped up rim of firm tissue located in the upper anterior wall and upper portion of right lateral wall. On cut section, the mass is firm and tan-white with hemorrhagic foci and patches of necrosis centrally and extends into the adipose tissue to a depth of 2.5 cm, to within 0.1 cm of the deep margin. The surrounding bladder mucosa is wrinkled and tan with a uniform 0.2 cm wall thickness. Bilateral ureteral orifices, adjacent to the trigone, are identified and probe patent. Photographs are taken.

[page 4 of 4]
Representative sections are submitted as follows:

- D1: Left ureter resection margin
- D2: Right ureter resection margin
- D3: Distal prostatic urethral margin
- D4: Prostate apex
- D5: Section of right prostate through verumontanum
- D6: Section of left prostate through verumontanum
- D7-D8: Section of right prostate above verumontanum
- D9-D10: Section of left prostate above verumontanum
- D11: Seminal vesicles and vas deferentia
- D12: Mass closest to inked outer surface
- D13: Mass at mucosal surface
- D14: Mass and adjacent grossly normal bladder wall
- D15: Uninvolved bladder mucosa bladder dome
- D16: Uninvolved bladder mucosa anterior wall
- D17: Uninvolved bladder mucosa posterior wall at trigone

E. The fifth container is additionally identified as, "#5 distal left ureter".

Received fresh and placed in formalin is an unoriented portion of ureter and attached fibroconnective tissue the specimen measures 0.9 x 0.6 x 0.2 cm. The portion of ureter is received previously opened with the mucosa exposed. The specimen is bisected and entirely submitted cassette E1.

F. The sixth container is additionally labeled as "#6 distal right ureter".

Received fresh and placed in formalin is a portion of ureter that measures 3.5 x 0.5 x 0.5 cm. The specimen is further oriented as stitch on non-margin side, which is inked yellow. The external surface is pink to tan smooth and glistening focally covered by yellow lobulated adipose tissue. The specimen is entirely submitted as follows:

- F1: Margin
- F2: Non-margin side
- F3-5: Remainder of the specimen

xxx

[]

Source: NCI Genomic Data Commons file 24ee131c-2021-4562-a129-7c8a332722c7 (TCGA-FD-A5BT.B5902DC7-953C-4944-B555-534BEDE6A248.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).